Somatic mutation profile of tumor specimen TCGA-DQ-5625-01A (aliquot TCGA-DQ-5625-01A-01D-1870-08) from TCGA case TCGA-DQ-5625, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; Tumor grade: G2; Age at diagnosis: 52.6 years (19,211 days).
Specimen TCGA-DQ-5625-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6b2db2e-bbf1-4643-8e20-b18409915186.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DQ-5625-10A (Blood Derived Normal), aliquot TCGA-DQ-5625-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d2bf4c4-870b-4e17-81c0-4f06a182ed79

The open-access MAF lists 203 somatic variants for this specimen: 157 protein-altering or splice-affecting, 42 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 42, Frame Shift Del 6, Nonsense Mutation 4, Intron 3, Frame Shift Ins 2, Splice Site 2, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1355A>G p.Y452C (on ENST00000521381 / NM_181523.3; = p.Y182C on NM_181504.4) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57130363; called by muse, mutect2, varscan2
- RHOA | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 42/191 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs1057519951, COSV69041613, COSV69042111, COSV69043712; ClinVar: likely pathogenic; called by muse, varscan2
- ACP2 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs4647764; called by muse, mutect2, varscan2
- ADAMTS10 | c.1586G>A p.G529E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs1555739393, CM147407, COSV99547039; called by muse, mutect2, varscan2
- ADAMTS9 | c.5503A>G p.T1835A | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99899647; called by muse, mutect2, varscan2
- AKT2 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV100251679; called by muse, mutect2, varscan2
- ANKMY1 | c.1381C>G p.L461V | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.038); catalogued as COSV99802408; called by muse, mutect2, varscan2
- ANO1 | c.2605G>C p.E869Q | Missense Mutation (SNP) | VAF 15/273 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100796951, COSV100797139; called by muse, mutect2
- ANO4 | c.2518G>A p.E840K (on ENST00000392977 / NM_001286615.2; = p.E805K on NM_178826.4) | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as COSV100153080; called by muse, mutect2, varscan2
- ANXA6 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.262); catalogued as rs370325414, COSV100637121; called by muse, mutect2, varscan2
- AP1G1 | c.17G>C p.R6T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV100250580; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1283T>A p.I428K | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV100771927; called by muse, mutect2, varscan2
- ATP10A | c.4400C>T p.A1467V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as rs771012252, COSV63520994; called by muse, mutect2, varscan2
- AUNIP | c.919C>G p.Q307E | Missense Mutation (SNP) | VAF 142/289 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV100961887; called by muse, mutect2, varscan2
- BBS10 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV101283402; called by muse, mutect2, varscan2
- BICD1 | c.2308G>C p.E770Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55682675; called by muse, mutect2, varscan2
- BIRC6 | c.9881C>G p.S3294* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV101428399, COSV70199617; called by muse, mutect2
- C5orf34 | c.983A>C p.Y328S | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.251); catalogued as COSV100175486; called by muse, mutect2, varscan2
- CCDC34 | c.801G>C p.E267D | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV100156612; called by muse, mutect2
- CD8A | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs200563616; called by muse, mutect2, varscan2
- CDH6 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.93); catalogued as COSV99419565; called by muse, mutect2
- CEBPZ | c.2261G>C p.R754T | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99305275; called by muse, mutect2, varscan2
- CERS2 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1284685209, COSV99644932; called by muse, mutect2, varscan2
- CES2 | c.993C>G p.D331E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV100399284; called by muse, mutect2, varscan2
- CHST8 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1370247769, COSV52863173; called by muse, mutect2, varscan2
- CLGN | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100346652; called by muse, mutect2, varscan2
- CLIP2 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV56280311; called by muse, mutect2, varscan2
- CNGB1 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs574295098, COSV51901177; called by muse, mutect2, varscan2
- CNTNAP2 | c.2279C>T p.S760L | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100667341; called by muse, mutect2, varscan2
- COL25A1 | c.1168T>G p.S390A | Missense Mutation (SNP) | VAF 126/384 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0.024); catalogued as COSV101211486; called by muse, mutect2, varscan2
- CSPG5 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.219); catalogued as COSV99273875; called by muse, mutect2, varscan2
- CSPG5 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.278); catalogued as rs1174084216, COSV99273877; called by muse, mutect2, varscan2
- CXCL2 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99933210; called by muse, mutect2, varscan2
- DCDC1 | c.250C>G p.H84D | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100663627; called by muse, mutect2, varscan2
- DENND6A | c.1275G>C p.Q425H | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.758); catalogued as COSV100231535; called by muse, varscan2
- DHODH | c.185C>A p.T62N | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as COSV99536926; called by muse, mutect2, varscan2
- DICER1 | c.439-1G>A p.X147_splice | Splice Site (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100602202, COSV100602531; called by muse, mutect2
- DMD | c.6646T>C p.F2216L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.036); catalogued as COSV100627790, COSV58894426; called by muse, mutect2, varscan2
- DNM2 | c.360C>G p.I120M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100117416; called by muse, mutect2, varscan2
- EPHA5 | c.2854G>A p.V952I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV56671297, COSV99899522; called by muse, mutect2
- EVPL | c.5408C>T p.S1803F | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs745942874, COSV56916589; called by muse, mutect2, varscan2
- FIBCD1 | c.802G>A p.G268S | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs1000145613, COSV99447212; called by muse, mutect2, varscan2
- FLT3LG | c.96C>G p.F32L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99201321; called by muse, mutect2, varscan2
- FOXQ1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as rs566840319, COSV99723300; called by muse, mutect2, varscan2
- FYN | c.1041A>T p.K347N | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV99991931; called by muse, mutect2, varscan2
- GOLGA3 | c.3022C>T p.R1008C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745845667, COSV99208902; called by muse, mutect2, varscan2
- HEATR5B | c.5398C>G p.Q1800E | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99249556; called by muse, mutect2, varscan2
- HIVEP3 | c.3319G>A p.D1107N | Missense Mutation (SNP) | VAF 51/91 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV99912980; called by muse, mutect2, varscan2
- HMCN1 | c.269A>T p.E90V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99630713; called by muse, mutect2, varscan2
- HPCAL1 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100324059; called by muse, mutect2, varscan2
- IARS1 | c.2237A>G p.N746S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV100986834; called by muse, mutect2, varscan2
- IFIH1 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.116); catalogued as COSV99718685; called by muse, mutect2, varscan2
- IFNA8 | c.264C>G p.F88L | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.164); catalogued as COSV101206910, COSV66505200; called by muse, mutect2, varscan2
- IGSF10 | c.7279G>T p.E2427* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | catalogued as COSV99180831; called by muse, mutect2, varscan2
- IGSF6 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV99193641; called by muse, mutect2, varscan2
- IL16 | c.3515G>A p.G1172E (on ENST00000302987 / NM_172217.5; = p.G471E on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100250859; called by muse, mutect2, varscan2
- ITGA4 | c.1013G>T p.R338I | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51998303, COSV52002278, COSV52003390; called by muse, mutect2, varscan2
- KCNH6 | c.2815G>C p.E939Q | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV59000332; called by muse, mutect2, varscan2
- KCNIP2 | c.275G>T p.G92V (on ENST00000356640 / NM_173191.3; = p.G107V on NM_014591.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV99493431; called by muse, mutect2, varscan2
- KCNS2 | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54637308, COSV54641660; called by muse, mutect2, varscan2
- KDM5A | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV66990887; called by muse, mutect2, varscan2
- KDM7A | c.371A>T p.K124M | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV99134625; called by muse, mutect2, varscan2
- KIF1A | c.2032A>T p.M678L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100241371; called by muse, mutect2
- KLHDC10 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as COSV100110950; called by muse, mutect2, varscan2
- LINGO4 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs200962386, COSV63215336; called by muse, mutect2
- LRP1B | c.7058A>T p.N2353I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV101257834; called by muse, mutect2, varscan2
- LRRC8E | c.1777G>T p.G593W | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100142682; called by muse, mutect2
- LRRN3 | c.78del p.V27Wfs*32 | Frame Shift Del (DEL) | VAF 41/123 reads (33%) | catalogued as COSV57818627; called by mutect2, pindel, varscan2
- LTO1 | c.184G>C p.A62P | Missense Mutation (SNP) | VAF 19/509 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.244); catalogued as COSV99654130; called by muse, mutect2
- MCUR1 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101001888; called by muse, mutect2, varscan2
- MDGA2 | c.1719T>G p.N573K (on ENST00000399232 / NM_001113498.2; = p.N275K on NM_182830.4) | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV100637424; called by muse, mutect2, varscan2
- MEF2C | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100425521, COSV60926486; called by muse, mutect2, varscan2
- MGAM | c.4903C>T p.R1635W | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868391857, COSV72074739; called by muse, mutect2, varscan2
- MKLN1 | c.26C>G p.A9G | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs200265321, COSV100759878; called by muse, mutect2, varscan2
- MMD2 | c.752A>G p.Y251C (on ENST00000404774 / NM_001100600.2; = p.Y227C on NM_198403.4) | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101287035; called by muse, mutect2
- MME | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.317); catalogued as rs574482291, COSV64706789, COSV64711544; called by muse, mutect2, varscan2
- MPDZ | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.158); catalogued as COSV100063037; called by muse, mutect2, varscan2
- MUC13 | c.712T>C p.Y238H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100222370; called by muse, mutect2, varscan2
- MUC3A | c.7615T>A p.S2539T | Missense Mutation (SNP) | VAF 82/320 reads (26%) | SIFT tolerated, low confidence (0.27); catalogued as rs768257467, COSV100114783; called by muse, mutect2, varscan2
- MVB12A | c.590T>A p.L197Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100396525; called by muse, mutect2, varscan2
- MYH13 | c.2344G>A p.D782N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99354371; called by muse, mutect2, varscan2
- MYO18B | c.5743G>C p.A1915P | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100124028; called by muse, mutect2, varscan2
- MYO7A | c.1279A>T p.K427* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV101289168; called by muse, mutect2, varscan2
- MYOCD | c.1835C>G p.A612G | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100590918; called by muse, varscan2
- NBN | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as rs753270166, COSV55376096, COSV99619656; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBPF10 | c.1020T>A p.F340L | Missense Mutation (SNP) | VAF 69/337 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100745160; called by muse, mutect2, varscan2
- NDUFS3 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99772368; called by muse, mutect2
- NEDD8 | c.164C>G p.T55R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV99164632; called by muse, mutect2, varscan2
- NEK8 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52044947, COSV99261994; called by muse, mutect2, varscan2
- NLRP8 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1436407482, COSV52583532; called by muse, mutect2, varscan2
- NMI | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99693406; called by muse, mutect2, varscan2
- NRXN3 | c.1404G>T p.M468I (on ENST00000335750 / NM_001330195.2; = p.M95I on NM_004796.6) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); catalogued as COSV100204845, COSV59784430; called by muse, mutect2, varscan2
- NUP210 | c.4400C>T p.S1467L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs147955019; called by muse, mutect2, varscan2
- OR5D13 | c.29G>C p.S10T | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100686895; called by muse, mutect2, varscan2
- PACRGL | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.095); catalogued as COSV54844815; called by muse, mutect2, varscan2
- PAF1 | c.735G>C p.M245I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.505); catalogued as COSV99655862; called by muse, mutect2, varscan2
- PAF1 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 29/122 reads (24%) | catalogued as COSV99655864; called by muse, mutect2, varscan2
- PARP4 | c.4717T>C p.W1573R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV101131702; called by muse, mutect2, varscan2
- PCDH7 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.976); catalogued as rs868551664, COSV100688422; called by muse, mutect2
- PIK3R4 | c.1368C>G p.I456M | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV100768470; called by muse, mutect2, varscan2
- PLEC | c.11741A>T p.E3914V (on ENST00000322810 / NM_201380.4; = p.E3804V on NM_000445.5) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV100515461; called by muse, mutect2
- PMP2 | c.195C>G p.F65L | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99808237; called by muse, mutect2, varscan2
- PORCN | c.451T>A p.S151T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as COSV100400461; called by muse, mutect2
- PPDPFL | c.137T>C p.L46S | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV100293147; called by muse, mutect2
- PPP1R13L | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as COSV100714790; called by muse, mutect2, varscan2
- PPRC1 | c.3026G>A p.R1009K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.104); catalogued as rs756058587, COSV99531758; called by muse, mutect2, varscan2
- PTGER4 | c.401G>C p.R134P | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV100201586, COSV56720357; called by muse, mutect2, varscan2
- QSER1 | c.2962G>C p.E988Q (on ENST00000399302; = p.E1117Q on NM_001076786.3) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV101234876; called by muse, mutect2, varscan2
- QSER1 | c.3270G>C p.Q1090H (on ENST00000399302; = p.Q1219H on NM_001076786.3) | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.315); catalogued as rs746915352, COSV101234877; called by muse, mutect2, varscan2
- QSER1 | c.3649G>C p.D1217H (on ENST00000399302; = p.D1346H on NM_001076786.3) | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV101234878; called by muse, mutect2, varscan2
- RACGAP1 | c.1225C>G p.L409V | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as rs893441125, COSV100407832; called by muse, mutect2, varscan2
- RARG | c.1213C>G p.P405A | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99914125; called by muse, varscan2
- RASGRF1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1166184207, COSV69177458; called by muse, mutect2, varscan2
- RBM34 | c.30G>C p.K10N | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV100783954, COSV100783980; called by muse, mutect2, varscan2
- RBM4 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV100029660; called by muse, mutect2, varscan2
- RGL4 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs145276888; called by muse, mutect2, varscan2
- RGS20 | c.852C>A p.F284L (on ENST00000297313 / NM_170587.4; = p.F137L on NM_003702.4) | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV99392208; called by muse, mutect2, varscan2
- RPGR | c.2617G>A p.D873N (on ENST00000339363 / NM_001367249.1; = p.D668N on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV100140115, COSV58834037; called by muse, mutect2, varscan2
- SBF1 | c.5143G>C p.D1715H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.799); catalogued as COSV99324138; called by muse, mutect2, varscan2
- SEC62 | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1241718311, COSV100427994; called by muse, mutect2, varscan2
- SERF2 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs765791045, COSV99988483, COSV99988555; called by muse, mutect2, varscan2
- SH3BP4 | c.461G>A p.R154K | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100749210; called by muse, mutect2, varscan2
- SH3GL3 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100196933; called by muse, mutect2, varscan2
- SHMT2 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.271); catalogued as rs776714754, COSV61075196; called by muse, mutect2, varscan2
- SHOC2 | c.902G>C p.R301T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.183); catalogued as COSV99510275; called by muse, mutect2, varscan2
- SHROOM2 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV101098765; called by muse, mutect2, varscan2
- SLC25A39 | c.392+1G>T p.X131_splice (on ENST00000377095 / NM_001143780.3; = p.X123_splice on NM_016016.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99835304; called by muse, mutect2, varscan2
- SLC9C1 | c.3302T>A p.F1101Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.388); catalogued as COSV99998157; called by muse, mutect2, varscan2
- SPTAN1 | c.6781C>G p.Q2261E | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.06); catalogued as COSV100823680; called by muse, mutect2, varscan2
- SPTAN1 | c.7182C>G p.F2394L | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100823682; called by muse, varscan2
- SUSD1 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100813361; called by muse, mutect2, varscan2
- TEKT1 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100106263; called by muse, varscan2
- TEKT1 | c.195G>C p.Q65H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as COSV100106267; called by muse, varscan2
- TMPRSS12 | c.665A>T p.N222I | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV101269118; called by muse, mutect2, varscan2
- TNFRSF11A | c.1625T>A p.F542Y | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99500299; called by muse, mutect2
- TRIOBP | c.4979C>G p.T1660S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as COSV100730934; called by muse, mutect2, varscan2
- TRMT10B | c.801G>C p.Q267H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV53051683; called by muse, mutect2, varscan2
- UGT1A8 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs374980275; called by muse, mutect2, varscan2
- USP7 | c.2827G>C p.E943Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as COSV61216500; called by muse, mutect2
- WAPL | c.3331C>T p.H1111Y | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV99556514; called by muse, mutect2, varscan2
- WIPF1 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 76/339 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1429764304, COSV55813655; called by muse, mutect2, varscan2
- WIPF3 | c.238A>T p.N80Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV99634771; called by muse, mutect2
- WNT9A | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.764); catalogued as rs745638843, COSV55297208, COSV99688302; called by muse, mutect2, varscan2
- YBX2 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756053394, COSV99142737; called by muse, mutect2, varscan2
- ZFYVE9 | c.1759C>A p.L587I | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as COSV99820185; called by muse, mutect2, varscan2
- ZIC2 | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.05); catalogued as rs919546828, COSV100891793; called by muse, mutect2, varscan2
- ZNF423 | c.130C>G p.Q44E (on ENST00000563137 / NM_001379286.1; = p.Q36E on NM_015069.4) | Missense Mutation (SNP) | VAF 49/260 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756709776, COSV52197594, COSV99282229; called by muse, mutect2, varscan2
- ZNF713 | c.23A>T p.D8V (on ENST00000633730 / NM_001366796.2; = p.D21V on NM_182633.3) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101289512; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100008432; called by muse, mutect2, varscan2
- CNOT10 | c.680dup p.Q228Pfs*9 | Frame Shift Ins (INS) | VAF 13/77 reads (17%) | called by mutect2, pindel, varscan2
- DDX11 | c.2267dup p.Q757Pfs*25 (on ENST00000545668 / NM_152438.2; = p.Q707Pfs*25 on NM_004399.3) | Frame Shift Ins (INS) | VAF 16/103 reads (16%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.2419_2421delinsAA p.E807Kfs*53 | Frame Shift Del (DEL) | VAF 43/120 reads (36%) | called by pindel, varscan2*
- HUWE1 | c.12177_12179del p.G4060del | In Frame Del (DEL) | VAF 14/54 reads (26%) | called by pindel, varscan2
- PAPSS2 | c.260_261del p.R87Kfs*18 | Frame Shift Del (DEL) | VAF 15/114 reads (13%) | called by mutect2, pindel, varscan2
- PLAG1 | c.98del p.N33Tfs*17 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | called by mutect2, pindel, varscan2
- PODXL | c.1556_1560del p.S519* (on ENST00000378555 / NM_001018111.3; = p.S487* on NM_005397.4) | Frame Shift Del (DEL) | VAF 59/217 reads (27%) | called by mutect2, pindel, varscan2
- ZNF618 | c.1888_1897del p.G630Ffs*8 (on ENST00000374126 / NM_001318042.2; = p.G537Ffs*8 on NM_133374.2) | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | called by mutect2, pindel
- ATRX | c.582T>A p.V194= | Silent (SNP) | VAF 51/150 reads (34%) | catalogued as COSV100969535; called by muse, mutect2, varscan2
- CACTIN | c.1638G>C p.L546= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99698613; called by muse, mutect2, varscan2
- CELSR1 | c.6396G>A p.L2132= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs1259584400, COSV99418708; called by muse, mutect2, varscan2
- CHSY1 | c.264C>T p.F88= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1264165567, COSV54254360, COSV54256229; called by muse, mutect2, varscan2
- CLIP1 | c.1999A>C p.R667= (on ENST00000620786 / NM_001247997.1; = p.R656= on NM_002956.2) | Silent (SNP) | VAF 35/161 reads (22%) | catalogued as COSV100211883; called by muse, mutect2, varscan2
- DHX30 | c.2364C>T p.S788= (on ENST00000445061 / NM_138615.3; = p.S749= on NM_014966.3) | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs147501030; called by muse, mutect2, varscan2
- EHMT2 | c.1593C>G p.V531= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV100977221; called by muse, mutect2, varscan2
- GDF15 | c.648C>T p.V216= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99416190; called by mutect2, varscan2
- GIT1 | c.1365G>C p.R455= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs145208703; called by muse, mutect2, varscan2
- ITSN1 | c.2904C>G p.L968= | Silent (SNP) | VAF 68/155 reads (44%) | catalogued as COSV101180575; called by muse, mutect2, varscan2
- KCNG3 | c.1248T>C p.Y416= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV100045156; called by muse, mutect2, varscan2
- MAGEB1 | c.822G>A p.P274= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as rs772666054, COSV100974859; called by muse, mutect2, varscan2
- MAP3K15 | c.2571G>A p.P857= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs770188034, COSV100134949; called by muse, varscan2
- MAPK11 | c.865C>T p.L289= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV99299438; called by muse, mutect2
- MINK1 | c.3261G>T p.L1087= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99545049; called by muse, mutect2, varscan2
- MS4A3 | c.90T>C p.N30= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV99614816; called by muse, mutect2, varscan2
- MUC4 | c.12972C>T p.G4324= (on ENST00000463781 / NM_018406.7; = p.G88= on NM_004532.6) | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as rs766468275, COSV100205133; called by muse, mutect2, varscan2
- MYH4 | c.2025G>C p.R675= | Silent (SNP) | VAF 29/161 reads (18%) | catalogued as rs1291867174, COSV99701506; called by muse, mutect2, varscan2
- NUDT8 | c.696G>A p.L232= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100039788; called by muse, mutect2, varscan2
- OR2G2 | c.612G>A p.V204= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as COSV100189785, COSV60740870; called by muse, mutect2, varscan2
- OR7D2 | c.378C>G p.V126= | Silent (SNP) | VAF 47/212 reads (22%) | called by muse, mutect2, varscan2
- PRMT3 | c.1110G>T p.V370= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as COSV100423978; called by muse, mutect2, varscan2
- RAF1 | c.1770G>A p.K590= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as COSV99312787; called by muse, mutect2, varscan2
- RHOBTB1 | c.636G>A p.R212= | Silent (SNP) | VAF 53/248 reads (21%) | catalogued as COSV100558528; called by muse, mutect2, varscan2
- RPTN | c.690G>A p.R230= | Silent (SNP) | VAF 86/266 reads (32%) | catalogued as rs759336271, COSV100285561; called by muse, mutect2, varscan2
- RYR1 | c.8613G>T p.L2871= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100616046; called by muse, mutect2, varscan2
- SALL1 | c.3327G>A p.P1109= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs375357921; called by muse, mutect2, varscan2
- SIM1 | c.1269C>T p.A423= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs753644529, COSV53494098; called by muse, mutect2, varscan2
- SPEG | c.3657C>T p.I1219= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100404774; called by muse, mutect2
- SPEG | c.3867G>A p.P1289= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs1322153647, COSV100403575; called by muse, mutect2, varscan2
- SQOR | c.432T>G p.A144= | Silent (SNP) | VAF 31/212 reads (15%) | catalogued as COSV99525852; called by muse, mutect2, varscan2
- STAB1 | c.1480C>A p.R494= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as rs770722351, COSV100401868; called by muse, mutect2, varscan2
- TEKT1 | c.201C>G p.L67= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100106265; called by muse, varscan2
- TMEM54 | c.561G>C p.L187= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV61275656; called by muse, mutect2, varscan2
- UMPS | c.1362C>T p.I454= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99229113; called by muse, mutect2, varscan2
- USP35 | c.1152C>T p.F384= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV71572612, COSV71572763; called by muse, mutect2, varscan2
- USP43 | c.3048C>G p.V1016= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99556784; called by muse, mutect2, varscan2
- YBX2 | c.975C>T p.F325= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99142735; called by muse, mutect2
- ZC3HAV1 | c.1017C>G p.L339= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as rs752215043, COSV99648717; called by muse, mutect2, varscan2
- ZFHX3 | c.11103C>T p.F3701= | Silent (SNP) | VAF 51/241 reads (21%) | catalogued as COSV99213334; called by muse, mutect2, varscan2
- ZNF550 | c.36G>A p.V12= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as rs369508910; called by muse, varscan2
- ZNF610 | c.708A>G p.E236= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100016878; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504945 C>A | 5'Flank (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2
- PRMT8 | c.76-1928T>A | Intron (SNP) | VAF 38/150 reads (25%) | catalogued as COSV99713469; called by muse, mutect2, varscan2
- WNK1 | c.1312-5417C>T | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as rs1338893652, COSV100267694; called by muse, mutect2
- XPO5 | c.2678-359del | Intron (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
